Somatic mutation profile of tumor specimen TCGA-DU-8166-01A (aliquot TCGA-DU-8166-01A-11D-2253-08) from TCGA case TCGA-DU-8166, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 29.1 years (10,641 days).
Specimen TCGA-DU-8166-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90a68d85-e102-403f-bca8-f4fab9e96cc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-8166-10A (Blood Derived Normal), aliquot TCGA-DU-8166-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af36d387-76d7-432d-be26-bdb2b7aae891

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 46/119 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 20/23 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGAP32 | c.4742G>A p.R1581Q (on ENST00000310343 / NM_001378025.1; = p.R1232Q on NM_014715.4) | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs765797475, COSV100089551, COSV59855102; called by muse, mutect2, varscan2
- ATRX | c.663-2A>G p.X221_splice | Splice Site (SNP) | VAF 50/159 reads (31%) | catalogued as COSV64872853, COSV64882642; called by muse, mutect2, varscan2
- BCL2L15 | c.292A>G p.T98A | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV63643297; called by muse, mutect2
- GALNT17 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.363); catalogued as rs752472906, COSV61153980, COSV61188172; called by muse, mutect2, varscan2
- KIF1A | c.3281G>A p.S1094N | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.918); catalogued as COSV57482485, COSV57500553; called by muse, mutect2, varscan2
- LUM | c.594A>T p.R198S | Missense Mutation (SNP) | VAF 8/224 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV57129067; called by muse, mutect2
- MYO15A | c.9487G>A p.V3163M | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.07); catalogued as rs750700068, COSV52765068; called by muse, mutect2
- NCOR1 | c.6725C>G p.T2242S | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV51994325; called by muse, mutect2
- SEZ6L | c.1777A>G p.T593A | Missense Mutation (SNP) | VAF 101/303 reads (33%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.669); catalogued as COSV50683724; called by muse, mutect2, varscan2
- SLIT1 | c.236A>G p.N79S | Missense Mutation (SNP) | VAF 100/206 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV56598051; called by muse, mutect2, varscan2
- TPRX1 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 16/241 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs758622199, COSV59117247; called by muse, mutect2
- TRIM15 | c.749T>C p.F250S | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs773460220, COSV64990346; called by muse, mutect2, varscan2
- TTLL9 | c.206A>C p.D69A | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as COSV60593926, COSV60595999; called by muse, mutect2, varscan2
- USH2A | c.9644T>C p.V3215A | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV56428392; called by muse, mutect2, varscan2
- FCGBP | c.1927G>T p.D643Y | Missense Mutation (SNP) | VAF 14/432 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- CD109 | c.795G>A p.T265= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs542993766, COSV54645487; called by muse, mutect2, varscan2
- CT55 | c.102C>G p.T34= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV52278101, COSV52278848; called by muse, mutect2, varscan2
- GPR180 | c.969G>C p.G323= | Silent (SNP) | VAF 24/240 reads (10%) | catalogued as COSV65386168; called by muse, mutect2
- RNPEP | c.1494G>T p.G498= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV55243845; called by muse, mutect2, varscan2
- SLC9A5 | c.2491C>T p.L831= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV55364554; called by muse, mutect2, varscan2
- PAXBP1 | c.2334+1688dup | Intron (INS) | VAF 4/21 reads (19%) | called by mutect2, pindel, varscan2
